Somatic mutation profile of tumor specimen MMRF_1386_1_BM_CD138pos (aliquot MMRF_1386_1_BM_CD138pos_T1_KAS5U_L00667) from MMRF case MMRF_1386, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.5 years (19,914 days).
Specimen MMRF_1386_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2319e04a-4248-475a-898e-f6fdf71ff76b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1386_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1386_1_PB_Whole_C2_KAS5U_L00680; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e270bf56-c1f0-431e-b37f-25c0be9e3e9e

The open-access MAF lists 53 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 11, Intron 6, Silent 4, 5'Flank 3, Splice Site 2, IGR 1, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACR | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV99334570; called by muse, mutect2, varscan2
- BAZ2A | c.5047C>T p.R1683W | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745785227, COSV51643261; called by muse, mutect2, varscan2
- CALD1 | c.2327G>A p.R776Q (on ENST00000361675 / NM_033138.4; = p.R521Q on NM_004342.7) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571684749, COSV62647050; called by muse, mutect2, varscan2
- IGHV2-70 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as rs369407281; called by muse, varscan2
- NCS1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970003; called by muse, mutect2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- OPCML | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as COSV59408802; called by muse, mutect2, varscan2
- RADIL | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as rs762208707, COSV68201424; called by muse, mutect2, varscan2
- ROBO1 | c.4184G>T p.G1395V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV71396541; called by muse, mutect2, varscan2
- SUMO2 | c.45C>G p.N15K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as rs749365427; called by muse, mutect2, varscan2
- TENT5C | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65616287; called by muse, mutect2, varscan2
- TMSB4X | c.-17+1G>T | Splice Site (SNP) | VAF 31/73 reads (42%) | catalogued as COSV66081196, COSV66081636; called by muse, mutect2, varscan2
- ZNF664 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100544499; called by muse, mutect2, varscan2
- ADCY8 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.188); called by muse, varscan2
- ANKRD11 | c.744+4G>A | Splice Region (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- CD63 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2
- FAT1 | c.3540T>A p.S1180R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IVD | c.226G>T p.E76* (on ENST00000651168; = p.E73* on NM_002225.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- LRRK2 | c.62_65dup p.R22Sfs*88 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | called by mutect2, varscan2
- MMRN1 | c.1827C>A p.D609E | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NRXN3 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMPCA | c.4_10del p.A2_?4 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.951T>G p.F317L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PSAP | c.910-28_914del p.X304_splice | Splice Site (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel
- ZMAT5 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMBT1 | c.6009T>C p.Y2003= (on ENST00000338354 / NM_001377530.1; = p.Y1246= on NM_004406.3) | Silent (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- MUC20 | c.57G>T p.G19= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs369400421; called by muse, mutect2
- MYBBP1A | c.69C>T p.A23= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs1257731910; called by muse, mutect2, varscan2
- RYR2 | c.1116T>C p.L372= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- AC020637.1 | n.1301G>T | RNA (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- AHCY | c.*526G>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ASIC4 | c.*695T>C | 3'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- C1orf122 | chr1:37807283 A>C | 5'Flank (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- CADM2 | chr3:84959460 T>A | 5'Flank (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- CADM2 | chr3:84959461 C>A | 5'Flank (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- COG3 | c.*755del | 3'UTR (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- DBNL | c.*694G>A | 3'UTR (SNP) | VAF 51/85 reads (60%) | called by muse, mutect2, varscan2
- DNAJC18 | c.*2304C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- ENTR1 | c.220+166G>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- EXOSC2 | c.270+57C>T | Intron (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- GLB1L3 | c.812-19C>A | Intron (SNP) | VAF 27/65 reads (42%) | catalogued as COSV66281033; called by muse, mutect2, varscan2
- GLIS3 | c.*3009A>T | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- IGF1R | c.*6734A>C | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 18/38 reads (47%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- INPP4B | chr4:142028002 T>G | 3'Flank (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-129834G>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- KDM4C | c.2994+637G>C | Intron (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+9016G>C | Intron (SNP) | VAF 25/81 reads (31%) | catalogued as rs944539808; called by muse, mutect2, varscan2
- OSER1 | c.*477T>C | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- PRRX1 | c.*377T>G | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*2790C>A | 3'UTR (SNP) | VAF 38/77 reads (49%) | catalogued as COSV54131002; called by muse, mutect2
- SP9 | c.*739T>C | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- Unknown | chr1:200342605 C>T | IGR (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
